Somatic mutation profile of tumor specimen TCGA-DK-A6B2-01A (aliquot TCGA-DK-A6B2-01A-11D-A30E-08) from TCGA case TCGA-DK-A6B2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 70.2 years (25,625 days).
Specimen TCGA-DK-A6B2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dec4a99-9535-4ec7-b1e8-f727fc8c036b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6B2-10A (Blood Derived Normal), aliquot TCGA-DK-A6B2-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a68feba-310a-426a-a8d5-aaf174f592cb

The open-access MAF lists 223 somatic variants for this specimen: 161 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 55, Nonsense Mutation 13, Frame Shift Del 9, Intron 5, Frame Shift Ins 1, RNA 1, 3'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- AATK | c.1917C>G p.F639L (on ENST00000326724 / NM_001080395.3; = p.F536L on NM_004920.2) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV58368838; called by muse, varscan2
- ABCC5 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 33/116 reads (28%) | catalogued as COSV99657473, COSV99657623; called by muse, mutect2, varscan2
- ABCC9 | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV53976200; called by muse, mutect2
- ABR | c.351G>A p.M117I (on ENST00000302538 / NM_021962.5; = p.M80I on NM_001092.5) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52147607; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3173C>T p.P1058L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65893657; called by muse, mutect2, varscan2
- ADGRA3 | c.1552C>T p.L518F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51564498; called by muse, mutect2, varscan2
- AHNAK2 | c.2041A>T p.K681* | Nonsense Mutation (SNP) | VAF 200/344 reads (58%) | catalogued as COSV100318766; called by muse, mutect2, varscan2
- ALMS1 | c.5996C>T p.S1999L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1352036989, COSV52513115; called by muse, mutect2, varscan2
- AMDHD2 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53551223; called by muse, mutect2, varscan2
- AOX1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV101021947; called by muse, mutect2, varscan2
- APLP1 | c.1601C>A p.A534E (on ENST00000221891 / NM_001024807.3; = p.A533E on NM_005166.4) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as COSV55704301; called by muse, mutect2, varscan2
- ARHGAP30 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV63517338, COSV63518749; called by muse, mutect2
- ARMC8 | c.1525C>T p.R509* (on ENST00000469044 / NM_001363941.2; = p.R495* on NM_015396.6) | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100509840; called by muse, mutect2
- ATAD2 | c.3595G>A p.E1199K | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs763830616, COSV54882598; called by muse, mutect2, varscan2
- BAZ2B | c.6325A>G p.T2109A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58603761; called by mutect2, varscan2
- BTBD2 | c.1276C>G p.H426D | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV55309442; called by muse, mutect2, varscan2
- BTBD8 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100730445; called by muse, mutect2
- CASP8AP2 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52748067; called by muse, mutect2, varscan2
- CDH23 | c.4624G>A p.G1542S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs1227430819, COSV99821883, COSV99823372; called by muse, mutect2, varscan2
- CEP152 | c.3960A>T p.Q1320H (on ENST00000380950 / NM_001194998.2; = p.Q1264H on NM_014985.4) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV57860826; called by mutect2, varscan2
- CFAP54 | c.6563C>T p.A2188V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61572901; called by muse, mutect2, varscan2
- CLEC4M | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV50220224; called by muse, mutect2, varscan2
- COL4A3 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.103); catalogued as rs775936375, COSV67416498; called by muse, mutect2, varscan2
- CR1L | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.09); catalogued as rs376930215; called by muse, mutect2, varscan2
- CT55 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV52278160; called by muse, mutect2
- CTNNA2 | c.2383G>C p.V795L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100559432, COSV58159510; called by muse, mutect2
- CTNNA3 | c.2139G>T p.M713I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV65525798; called by muse, mutect2, varscan2
- CTNND2 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs773500605, COSV58883891; called by muse, mutect2, varscan2
- DBX2 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as COSV60338231; called by muse, mutect2, varscan2
- DGKH | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54934804; called by muse, mutect2, varscan2
- DIP2C | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs376371262; called by muse, mutect2, varscan2
- DMPK | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52179432; called by muse, mutect2, varscan2
- DMXL1 | c.5389G>C p.E1797Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV60714676; called by muse, mutect2, varscan2
- DNAH5 | c.8168A>T p.Q2723L | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54234385; called by muse, mutect2, varscan2
- DPP10 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV59695701; called by muse, mutect2
- DPP3 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438946104, COSV64755875; called by muse, mutect2, varscan2
- DSP | c.4565C>G p.T1522R | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV65793138, COSV65793568; called by muse, mutect2, varscan2
- ELP4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV63354299; called by muse, mutect2, varscan2
- ESS2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755792682, COSV52817361; called by muse, mutect2, varscan2
- FAM126A | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV69471960; called by muse, mutect2, varscan2
- FAM9C | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61775715; called by muse, mutect2, varscan2
- FAT4 | c.12808T>C p.Y4270H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58692479; called by muse, varscan2
- FBN3 | c.5335G>A p.D1779N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV54464329; called by muse, mutect2, varscan2
- FKBPL | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.286); catalogued as rs368026293; called by muse, mutect2, varscan2
- FOXE1 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100909977; called by muse, varscan2
- GAA | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56408429, COSV56409375; called by muse, mutect2, varscan2
- GABRQ | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs782168254, COSV64782599; called by muse, mutect2, varscan2
- GRIA4 | c.1748A>T p.E583V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as COSV56903969; called by muse, mutect2, varscan2
- GRID1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60035711; called by muse, mutect2, varscan2
- GXYLT2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764141156, COSV67474443; called by muse, mutect2, varscan2
- H1-7 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs550344470, COSV58602049; called by muse, mutect2, varscan2
- HEPH | c.1408G>A p.V470M (on ENST00000343002; = p.V203M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57966161; called by muse, mutect2, varscan2
- HIP1 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 56/158 reads (35%) | catalogued as COSV100418100; called by muse, mutect2, varscan2
- HOMEZ | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 118/199 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV62536966, COSV62537348; called by muse, mutect2, varscan2
- HPD | c.1022A>G p.Q341R | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56642417; called by muse, mutect2, varscan2
- IL7R | c.936T>A p.D312E | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV57409803; called by muse, mutect2, varscan2
- ITSN1 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66084001; called by muse, varscan2
- KCND2 | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58573530; called by muse, mutect2, varscan2
- KCNS2 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as COSV54639206; called by muse, mutect2
- KIF21A | c.4622del p.P1541Lfs*6 (on ENST00000361418 / NM_001378440.1; = p.P1528Lfs*6 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as COSV62771708; called by mutect2, pindel, varscan2
- KMT2A | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63287868; called by muse, mutect2, varscan2
- KMT2C | c.1504C>A p.H502N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51284703, COSV51455776; called by muse, mutect2, varscan2
- KRTAP13-2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV67762093; called by muse, mutect2, varscan2
- LANCL3 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV101065741; called by muse, mutect2, varscan2
- LCP2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50453291; called by muse, mutect2, varscan2
- LHFPL5 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.955); catalogued as COSV100799023; called by muse, mutect2
- LIPG | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1283358057, COSV54296799; called by muse, mutect2, varscan2
- LMTK2 | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV51998367, COSV52004574; called by muse, mutect2, varscan2
- LOXL4 | c.688del p.D230Tfs*6 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as COSV53259623; called by mutect2, pindel, varscan2
- LRIF1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs754666576, COSV63897309, COSV63897602; called by muse, mutect2, varscan2
- MAD2L1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs78047690, COSV56636656, COSV56637106; called by muse, mutect2, varscan2
- MATN4 | c.916C>G p.H306D (on ENST00000372754; = p.H265D on NM_003833.4) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | PolyPhen benign (0.082); catalogued as COSV61351822; called by muse, mutect2
- MED12 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100379661; called by muse, mutect2, varscan2
- MGAT5B | c.1119G>C p.Q373H | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV56931242; called by muse, mutect2, varscan2
- MMP8 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99368798; called by muse, mutect2
- MRPL44 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.347); catalogued as COSV51313435; called by muse, mutect2, varscan2
- MUC17 | c.7263del p.V2422Lfs*37 | Frame Shift Del (DEL) | VAF 246/752 reads (33%) | catalogued as COSV60292894; called by mutect2, pindel, varscan2
- MX1 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV55817550; called by muse, mutect2, varscan2
- MYH9 | c.5307G>T p.E1769D | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53388439; called by muse, mutect2, varscan2
- MYOC | c.1030G>C p.V344L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50675714; called by muse, mutect2, varscan2
- MZT2A | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs777626407, COSV58312238; called by muse, mutect2, varscan2
- NAV3 | c.7088A>T p.Q2363L (on ENST00000397909 / NM_001024383.2; = p.Q2341L on NM_014903.6) | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57089694; called by muse, mutect2
- NCR1 | c.179T>A p.L60Q | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52557203; called by muse, mutect2, varscan2
- NOX3 | c.1328G>C p.C443S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50155110; called by muse, mutect2, varscan2
- NR0B2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs751780945, CM033798, COSV54259869; called by muse, mutect2, varscan2
- NR1I3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63468427; called by muse, mutect2
- NRAP | c.3350C>T p.P1117L (on ENST00000359988 / NM_001322945.2; = p.P1082L on NM_006175.4) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs770785299, COSV63490831, COSV63491788; called by muse, mutect2, varscan2
- NRXN1 | c.2243C>A p.S748Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100454241, COSV58463917; called by muse, mutect2, varscan2
- NUP210 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV54408374; called by muse, mutect2, varscan2
- OLFM1 | c.325G>T p.E109* (on ENST00000371793 / NM_001282611.2; = p.E91* on NM_006334.4) | Nonsense Mutation (SNP) | VAF 50/76 reads (66%) | catalogued as COSV99424225; called by muse, mutect2, varscan2
- OR13C5 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV101053162; called by muse, mutect2
- OR5D14 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV59456968; called by muse, mutect2, varscan2
- PCDHB13 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV53397966; called by muse, mutect2, varscan2
- PFKM | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100402693, COSV56658428; called by muse, mutect2, varscan2
- PICALM | c.390T>A p.Y130* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100708180; called by muse, mutect2, varscan2
- PIK3CA | c.2868G>C p.L956F | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55943522; called by muse, mutect2, varscan2
- PLCH1 | c.3953G>C p.S1318T (on ENST00000340059 / NM_001130960.2; = p.S1310T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); catalogued as COSV58201940; called by muse, mutect2, varscan2
- PLCZ1 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56854611; called by muse, mutect2
- PLEKHA5 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54704056; called by muse, mutect2, varscan2
- PLEKHF2 | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59541747; called by muse, mutect2, varscan2
- PLEKHG3 | c.1197_1211del p.R400_E404del (on ENST00000394691; = p.R456_E460del on NM_001308147.2) | In Frame Del (DEL) | VAF 18/43 reads (42%) | catalogued as COSV55980992; called by mutect2, pindel, varscan2
- PLXNA4 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV58136849; called by muse, mutect2, varscan2
- POTEE | c.2809G>C p.E937Q | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV58234445, COSV58236147, COSV58237570; called by muse, mutect2, varscan2
- PRKDC | c.9720G>A p.M3240I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs753361989, COSV58056108, COSV58057142; called by muse, mutect2, varscan2
- PRPF3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV61395321; called by muse, mutect2, varscan2
- PSTK | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as rs759975765, COSV64398523; called by muse, mutect2, varscan2
- PTPRZ1 | c.2905A>T p.I969L | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV66439746; called by muse, mutect2, varscan2
- PXDNL | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320433988, COSV62491078; called by muse, mutect2
- PYGO1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs770278178, COSV57348397; called by muse, mutect2, varscan2
- RAI2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.281); catalogued as COSV58964957; called by muse, mutect2, varscan2
- RALGPS2 | c.1381C>G p.Q461E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.047); catalogued as COSV62678628, COSV62678803; called by muse, mutect2, varscan2
- RBM25 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.745); catalogued as rs775819740, COSV56200649; called by muse, varscan2
- RIPK4 | c.1339G>A p.D447N (on ENST00000352483; = p.D399N on NM_020639.3) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs756317969, COSV60186431; called by muse, mutect2, varscan2
- RPS6KC1 | c.2810T>C p.L937S | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65300600; called by muse, mutect2, varscan2
- RYR2 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100768915, COSV63693044; called by muse, mutect2, varscan2
- SBF1 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV62367741; called by muse, mutect2, varscan2
- SF3B3 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56788789; called by muse, mutect2, varscan2
- SH3BP4 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs1281912975, COSV60644485; called by muse, mutect2, varscan2
- SLC12A4 | c.81C>A p.D27E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.057); catalogued as COSV57931371; called by muse, mutect2
- SLC6A15 | c.2062C>G p.P688A | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV57025424; called by muse, mutect2
- SLITRK5 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs748694724, COSV61523654; called by muse, mutect2, varscan2
- SLITRK6 | c.1808A>C p.D603A | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV68390546; called by muse, mutect2, varscan2
- SOX1 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100447073; called by muse, mutect2, varscan2
- SPART | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62086406; called by muse, mutect2, varscan2
- SRP72 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs764520914, COSV100714369; called by muse, mutect2
- SRSF4 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs188144655, COSV65695008; called by muse, mutect2, varscan2
- SRSF8 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as COSV101475781, COSV71665554; called by muse, mutect2, varscan2
- STXBP5L | c.3226G>C p.E1076Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV56519401; called by muse, mutect2, varscan2
- SUPT16H | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53525817; called by muse, mutect2, varscan2
- SUPT3H | c.219G>T p.L73= (on ENST00000371460 / NM_181356.3; = p.L62= on NM_003599.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/71 reads (13%) | catalogued as COSV60942424; called by muse, mutect2, varscan2
- SYNJ1 | c.1511A>G p.N504S | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV59150656; called by muse, mutect2, varscan2
- TBC1D28 | c.450C>G p.S150R | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV100561076; called by muse, mutect2, varscan2
- TGS1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1187329114, COSV52700997; called by muse, mutect2
- TICRR | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV51542839; called by muse, mutect2, varscan2
- TIE1 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100992162; called by muse, mutect2, varscan2
- TLL1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1368243570, COSV50261381, COSV50295756; called by muse, mutect2, varscan2
- TNIP3 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV50249614; called by muse, mutect2, varscan2
- TOGARAM1 | c.4976G>A p.G1659E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV63893025; called by muse, mutect2, varscan2
- TRIM17 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52858522, COSV99488572; called by muse, mutect2, varscan2
- TRIOBP | c.6724C>T p.R2242C (on ENST00000644935 / NM_001039141.3; = p.R529C on NM_007032.5) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779968784, COSV60379793; called by muse, mutect2, varscan2
- TRPM6 | c.5809A>G p.I1937V | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV62514554; called by muse, mutect2, varscan2
- TUBB8 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV100226188; called by muse, mutect2, varscan2
- VPS52 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101460422, COSV71403529; called by muse, mutect2, varscan2
- VSTM1 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs199504672, COSV58075441; called by muse, mutect2, varscan2
- XPO7 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53016368, COSV53020894; called by muse, mutect2, varscan2
- YIPF3 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs768159959, COSV58305494; called by muse, mutect2, varscan2
- ZFAND6 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV55712421, COSV99928350; called by muse, mutect2, varscan2
- ZNF25 | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56922000, COSV56922974; called by muse, mutect2, varscan2
- ZNF608 | c.4196T>C p.V1399A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.054); catalogued as COSV60438802; called by muse, mutect2, varscan2
- ZNF646 | c.1510C>A p.L504I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56215834; called by muse, mutect2, varscan2
- ZNF668 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100336849; called by muse, mutect2, varscan2
- ANK3 | c.9271del p.T3091Lfs*24 | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.644del p.G215Dfs*9 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- E2F8 | c.390_430del p.N131Rfs*7 | Frame Shift Del (DEL) | VAF 4/54 reads (7%) | called by mutect2, pindel
- HSPA12A | c.392del p.K131Sfs*11 | Frame Shift Del (DEL) | VAF 19/133 reads (14%) | called by mutect2, pindel, varscan2
- KRTAP5-11 | c.213del p.S72Afs*99 | Frame Shift Del (DEL) | VAF 49/287 reads (17%) | called by mutect2, pindel, varscan2
- MARK2 | c.1644del p.T549Rfs*67 (on ENST00000402010 / NM_001039469.2; = p.T515Rfs*67 on NM_017490.4) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- NDUFAF2 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); called by muse, mutect2
- PCDH7 | c.2269G>C p.V757L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLCD1 | c.123_124dup p.Y42Sfs*68 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- AASDH | c.984C>T p.L328= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV52707813; called by muse, mutect2, varscan2
- AC009779.3 | c.368G>A p.*123= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV57676623; called by muse, mutect2, varscan2
- ANKRD34A | c.1374G>A p.A458= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs782073652, COSV60161243; called by muse, mutect2, varscan2
- BBS9 | c.1833C>T p.L611= (on ENST00000242067 / NM_001348036.1; = p.L571= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs902126821, COSV54173931; called by muse, mutect2, varscan2
- BTBD8 | c.1056G>A p.E352= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100730446; called by muse, mutect2
- CACNA1G | c.3447G>A p.E1149= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV61730901; called by muse, mutect2, varscan2
- CELSR2 | c.4569G>C p.L1523= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV54774412; called by muse, mutect2, varscan2
- CEMIP | c.2046C>T p.L682= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99587204; called by muse, mutect2, varscan2
- CNTN1 | c.1491A>G p.G497= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV61641485; called by muse, mutect2, varscan2
- COL4A5 | c.1689G>A p.L563= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV60364449; called by muse, mutect2, varscan2
- DNAH8 | c.11979A>T p.V3993= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV59457639; called by muse, mutect2, varscan2
- DPPA5 | c.165C>T p.L55= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs769245148, COSV64875704, COSV64875797; called by muse, mutect2, varscan2
- ERBB4 | c.1920C>A p.G640= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV53546467, COSV53572354; called by muse, mutect2, varscan2
- EYA1 | c.1617G>A p.E539= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV58165843; called by muse, mutect2, varscan2
- FLG2 | c.4119T>A p.A1373= | Silent (SNP) | VAF 168/541 reads (31%) | catalogued as COSV101166214, COSV66169763; called by muse, mutect2, varscan2
- GDA | c.849C>T p.L283= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1325814709, COSV52994577; called by muse, mutect2, varscan2
- GPR4 | c.117G>A p.L39= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as rs1169008904, COSV59917425; called by muse, mutect2, varscan2
- GUCY1A1 | c.243G>T p.L81= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV56652900, COSV56656529; called by muse, mutect2, varscan2
- HUNK | c.522A>T p.V174= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as rs769707930, COSV54230439; called by muse, mutect2, varscan2
- HYAL3 | c.945C>T p.G315= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs782138560, COSV60186946; called by muse, mutect2, varscan2
- IGHG3 | c.1104G>A p.Q368= | Silent (SNP) | VAF 87/176 reads (49%) | called by muse, mutect2
- ITPKB | c.2343C>T p.P781= | Silent (SNP) | VAF 158/287 reads (55%) | catalogued as rs1057255748, COSV55264295; called by muse, mutect2, varscan2
- LCT | c.1470G>A p.E490= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV51545945, COSV51552180; called by muse, mutect2, varscan2
- LRP1B | c.609A>G p.P203= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV67238246; called by muse, mutect2, varscan2
- LRRC30 | c.192C>T p.P64= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs771985235, COSV101274385, COSV67301906; called by muse, mutect2, varscan2
- LRRC37A3 | c.4041G>T p.A1347= | Silent (SNP) | VAF 79/190 reads (42%) | catalogued as COSV58535780, COSV58537164; called by muse, mutect2, varscan2
- LTBP4 | c.180G>A p.T60= (on ENST00000308370 / NM_001042544.1; = p.R17H on NM_003573.2) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV52584234; called by muse, mutect2, varscan2
- LY9 | c.1890G>A p.R630= | Silent (SNP) | VAF 19/310 reads (6%) | catalogued as COSV54435170; called by muse, mutect2
- MAGEB18 | c.372G>A p.T124= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs773395698, COSV57463775; called by muse, mutect2, varscan2
- MLIP | c.474T>C p.A158= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV51431996; called by muse, mutect2, varscan2
- MOGAT2 | c.675C>A p.S225= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV52220174; called by muse, varscan2
- NCKAP5 | c.1221G>A p.K407= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs768954427, COSV58453208; called by muse, mutect2, varscan2
- NCOR1 | c.6501C>T p.L2167= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs747250940, COSV51981021; called by muse, mutect2, varscan2
- NOTCH1 | c.5901G>A p.A1967= | Silent (SNP) | VAF 29/222 reads (13%) | catalogued as rs762092431, COSV53063055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTRK2 | c.2055G>A p.G685= (on ENST00000323115 / NM_001369534.1; = p.G701= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs370505207; called by muse, mutect2, varscan2
- OCLN | c.330C>A p.G110= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV62285564; called by muse, mutect2, varscan2
- OR4C11 | c.477C>T p.I159= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV56352584; called by muse, mutect2, varscan2
- OVCH1 | c.3042T>C p.P1014= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as COSV58964777; called by muse, mutect2, varscan2
- PGBD5 | c.1137G>A p.L379= (on ENST00000525115; = p.L448= on NM_001258311.2) | Silent (SNP) | VAF 111/227 reads (49%) | catalogued as COSV58412258; called by muse, mutect2
- RNASET2 | c.714G>C p.L238= | Silent (SNP) | VAF 63/366 reads (17%) | catalogued as COSV50351723; called by muse, mutect2, varscan2
- RYR2 | c.9964T>C p.L3322= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV63693050; called by muse, mutect2, varscan2
- SCN11A | c.1110T>A p.R370= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as COSV56572562, COSV56580420; called by muse, mutect2, varscan2
- SEPTIN12 | c.285G>A p.L95= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV51617691; called by muse, mutect2, varscan2
- SLCO1C1 | c.1252A>C p.R418= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV56874766; called by muse, mutect2, varscan2
- SMARCC2 | c.3375C>T p.F1125= | Silent (SNP) | VAF 62/155 reads (40%) | catalogued as rs768295128, COSV53237211; called by muse, mutect2, varscan2
- SRSF8 | c.708G>T p.S236= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs182269432, COSV71665555; called by muse, mutect2, varscan2
- TMEM179B | c.579A>G p.P193= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as COSV53669535; called by muse, mutect2, varscan2
- TONSL | c.3597C>T p.N1199= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as rs374357745, COSV52871206; called by muse, mutect2, varscan2
- TRIM9 | c.1563C>T p.V521= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV53619246, COSV53624882; called by muse, mutect2, varscan2
- TSC2 | c.4809C>T p.D1603= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs147578602; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TTN | c.37956T>A p.L12652= (on ENST00000591111; = p.L5228= on NM_003319.4) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV60150779; called by muse, mutect2, varscan2
- UNC93A | c.21C>T p.N7= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs374011006; called by muse, mutect2, varscan2
- ZDBF2 | c.6333G>A p.P2111= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs748503293, COSV65627358; called by mutect2, varscan2
- ZNF70 | c.1200C>T p.F400= | Silent (SNP) | VAF 82/153 reads (54%) | catalogued as COSV59533176; called by muse, mutect2, varscan2
- ZNF70 | c.969C>T p.L323= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV59533187; called by muse, mutect2, varscan2
- AZIN2 | c.1029+3696C>G | Intron (SNP) | VAF 13/23 reads (57%) | catalogued as COSV53858422; called by muse, mutect2, varscan2
- CLASP2 | c.716-405G>A | Intron (SNP) | VAF 23/134 reads (17%) | catalogued as COSV56285682; called by muse, mutect2, varscan2
- DLG2 | c.205-65571A>G | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV54657252; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049839 C>G | 3'Flank (SNP) | VAF 5/33 reads (15%) | catalogued as COSV51535159, COSV99290791; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-148G>A | Intron (SNP) | VAF 40/115 reads (35%) | catalogued as COSV68923847; called by muse, mutect2, varscan2
- RAVER1 | c.1431+342C>G | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53346427; called by muse, mutect2, varscan2
- RPL23AP42 | n.281A>G | RNA (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
